Surgical pathology report (de-identified scan), TCGA case TCGA-HC-7741, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-7741-01C (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Right pelvic lymph node:
Benign, hyperplasia.

B. Left pelvic lymph node:
Benign, hyperplasia.

C. Radical prostatectomy:
Carcinoma.

Tumor Characteristics:

1. Histologic type: Adenocarcinoma, conventional type. ✓
2. Gleason Grade:
- a. Primary pattern: 3/5.
- b. Secondary pattern: 4/5.
- c. Score: 7/10. *
3. Tumor involves: Both lobes. *
4. Tumor quantitation: Tumor involves approximately 25% of the specimen.
5. Seminal vesicle involvement: Yes, left seminal vesicle. *
6. Extra-capsular tumor extension: No.
7. Lympho-vascular space invasion: Yes.
8. Perineural space invasion: Yes.
9. High grade PIN: Present.

Surgical Margin Status:

1. Bladder Neck: Negative.
2. Apical (inferior): Negative.
3. Inked prostatic margin: Negative.

Lymph Node Status:

1. Total number of lymph nodes examined: 2.
2. Number of lymph nodes containing metastatic carcinoma: None.

Other significant findings:

1. Frozen section correlation statement: All three frozen section diagnoses are confirmed.
2. Other findings: Status post treatment changes are noted.
3. pTNM stage: pT3b, N0, MX.

D. Bladder neck: Benign, no pathological diagnosis.

[page 2 of 2]
PATIENT INFORMATION

LABORATORY INFORMATION

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis:

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

A. Right pelvic lymph node with frozen section

B. Left pelvic lymph node with frozen section

C. Prostate

D. Bladder neck with frozen section

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in four containers labeled with the patient's name:

A. Container A is additionally labeled #1 and contains a 3.5 x 2.0 x 0.7 cm aggregate of yellow-tan fibroadipose tissue which is sectioned to reveal two pink-tan, firm, fatty nodules consistent with possible lymph node. They are 0.9 and 1.3 cm in greatest dimension. Portions of these nodules are submitted for frozen section with the residual entirely resubmitted for permanent section in cassette A1 labeled [redacted] All remaining possible lymphoid tissue is submitted in cassette A2 labeled [redacted]

B. Container B is additionally labeled left pelvic lymph node and contains a 50 x 3.0 x 1.0 cm aggregate of yellow-tan fibrofatty soft tissue containing multiple possible firm, fatty lymph node ranging from 0.1 up to 1.0 cm in greatest dimension. A representative section is submitted for frozen section with the residual entirely resubmitted for permanent section in cassette B1 labeled [redacted] Additional possible whole lymph nodes are submitted in cassette B2 labeled [redacted]

C. Container C is additionally labeled prostate and contains a 34.1 gm, 4.5 x 3.5 x 3.0 cm prostate with attached bilateral adnexa, 2.5 x 2.0 x 1.0 cm in overall dimension. The specimen has been previously inked as follows: right side red and left side blue. The right side is now over-inked with black. The base and the apical margins are coned and serially sectioned. The remainder of the specimen is serially sectioned to reveal a pink-tan, focally cystic cut surface with diffuse periurethral nodularity. No discrete lesions are identified. Representative sections are submitted in cassettes C1-18 labeled [redacted] Designated as follows: C1 right prostate/seminal vesicle junction; C2 left prostate/seminal vesicle junction; C3-4 apical margin, perpendicular; C5-6 base margin, perpendicular; C7-9 right anterior, apex to base; C10-12 right posterior, apex to base; C13-15 left anterior, apex to base; C16-18 left posterior, apex to base. Additionally, a yellow and green cassette are submitted for genomic research labeled [redacted]

D. Container D is additionally labeled bladder neck and contains a portion of rubbery tan-white tissue, 0.6 cm in diameter with stitch on one aspect which is inked red, bisected, and entirely submitted for frozen section with the residual entirely resubmitted for permanent section in cassette D labeled [redacted]

INTRA-OPERATIVE CONSULTATION:

Frozen section part A: No metastatic carcinoma identified.

Frozen section part B: No metastatic carcinoma identified.

Frozen section part D: Line of resection free of tumor.

MICROSCOPIC EXAMINATION:

All three frozen section diagnoses are confirmed.

Source: NCI Genomic Data Commons file 3b8ebb92-a498-4f53-8eb4-7bc56ac3ac85 (TCGA-HC-7741.7FBF6EE1-60F4-4BB6-ABF2-FC97791128B5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).